Somatic mutation profile of tumor specimen TCGA-D1-A1NW-01A (aliquot TCGA-D1-A1NW-01A-11D-A14K-09) from TCGA case TCGA-D1-A1NW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 72.7 years (26,556 days).
Specimen TCGA-D1-A1NW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06c32f5b-21d2-4cb1-87da-6373991a0c08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1NW-10A (Blood Derived Normal), aliquot TCGA-D1-A1NW-10A-01W-A16I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ab11bd2-1ec8-465a-b30c-59b9b130ca17

The open-access MAF lists 52 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 36, Silent 10, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 34/51 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP9 | c.9647T>A p.F3216Y (on ENST00000359028; = p.F3192Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100663176; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99784588; called by muse, mutect2
- ARHGAP21 | c.232T>A p.F78I | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100903727; called by muse, mutect2
- ASIC3 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs138242995; called by muse, mutect2, varscan2
- CACNA1B | c.4756C>T p.R1586C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773522880, COSV99500063; called by muse, mutect2, varscan2
- CAMKV | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV56554922; called by muse, mutect2, varscan2
- CAMSAP1 | c.2300A>G p.E767G | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100410470; called by muse, mutect2, varscan2
- CD300C | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs375373142; called by muse, mutect2, varscan2
- CDH11 | c.1359G>A p.W453* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | catalogued as COSV51770173, COSV51771651; called by muse, mutect2, varscan2
- CIB2 | c.67A>G p.N23D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99363479; called by muse, mutect2, varscan2
- CREB3L1 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as COSV99915344; called by muse, mutect2, varscan2
- DEK | c.896A>T p.K299I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99789162; called by muse, mutect2, varscan2
- DOCK11 | c.4786G>A p.D1596N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99354822; called by muse, mutect2, varscan2
- DOCK11 | c.4787A>C p.D1596A | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99354826; called by muse, mutect2, varscan2
- EEF1A2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as COSV99419982; called by muse, mutect2, varscan2
- EIF2D | c.1510-1G>A p.X504_splice | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as rs1553409535, COSV99663097; called by muse, mutect2, varscan2
- GFAP | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.209); catalogued as COSV99493652; called by mutect2, varscan2
- GOLGA6L9 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1348789502; called by mutect2, varscan2
- GTF3C2 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs544220164, CM142419, COSV99273141; called by muse, mutect2, varscan2
- HNRNPDL | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99787238; called by muse, mutect2
- IHH | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1469349097, COSV55393117, COSV99838815; called by muse, mutect2, varscan2
- KRT4 | c.807C>G p.I269M | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99543237; called by muse, mutect2
- LCN1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV55018071; called by mutect2, varscan2
- NDN | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.78); PolyPhen benign (0.134); catalogued as COSV100086306, COSV100086746; called by muse, varscan2
- NUFIP2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99837664; called by muse, mutect2, varscan2
- OR5K4 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100721413; called by muse, mutect2, varscan2
- PCDHGA11 | c.430A>C p.S144R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.359); catalogued as COSV99547754; called by muse, mutect2, varscan2
- PHKA1 | c.3047G>T p.R1016I | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100263971; called by muse, mutect2, varscan2
- RAB39A | c.286A>C p.T96P | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100269316; called by muse, mutect2
- RNF6 | c.1832T>C p.I611T | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100644680; called by muse, mutect2
- RTL9 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101511807; called by muse, mutect2, varscan2
- RTL9 | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.49); catalogued as COSV101511808; called by muse, mutect2, varscan2
- SH3RF1 | c.2562T>G p.D854E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99499559; called by muse, mutect2, varscan2
- SLC30A2 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.259); catalogued as rs1170235044, COSV100958628; called by muse, mutect2
- TTPAL | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV52828506, COSV99375580; called by mutect2, varscan2
- WDR20 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV100085515; called by muse, mutect2, varscan2
- ZNF225 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV99489627; called by muse, mutect2, varscan2
- H3C4 | c.239_257del p.K80Rfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- IK | c.587_590+37del p.X196_splice | Splice Site (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- NUMB | c.51_53del p.E18del | In Frame Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- ASB3 | c.42T>G p.V14= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV99712560; called by muse, mutect2, varscan2
- CNIH3 | c.255G>A p.A85= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs753238239, COSV99686279; called by muse, mutect2, varscan2
- DHX30 | c.3309C>T p.T1103= (on ENST00000445061 / NM_138615.3; = p.T1064= on NM_014966.3) | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs754405761, COSV53135737, COSV53139277; called by muse, mutect2, varscan2
- INKA2 | c.795C>T p.T265= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs200332005, COSV61877290; called by mutect2, varscan2
- JUN | c.808C>A p.R270= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs770259877, COSV100973508; called by muse, mutect2, varscan2
- MOB2 | c.118C>T p.L40= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100326704; called by muse, mutect2
- PCDH19 | c.864C>G p.L288= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV55262247; called by muse, mutect2, varscan2
- PITPNC1 | c.103C>A p.R35= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs368380321, COSV100084210, COSV55448654; called by mutect2, varscan2
- PTPRD | c.2673C>T p.Y891= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs1055243561, COSV100647270; called by muse, mutect2, varscan2
- ZNF548 | c.1359G>A p.E453= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100278310; called by muse, mutect2
